National Lung Screening Trial (NLST) participant 204421 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 62 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 35 effective mAs, display field of view 28 cm, reconstruction filter Siemens, other.
- T1: No screening result: Not Expected - Death in screening window.
- T2: No screening result: Not Expected - Death before screening window.

Abnormalities recorded by the reading radiologist on the CT screens (2 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 24 mm, longest perpendicular diameter 20 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 31.
- T0 abnormality 2: Emphysema.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 24, study year T0. Site: main bronchus (ICD-O-3 C34.0), determined from histology. Primary tumour location: left hilum, left main stem bronchus. Histology: oat cell carcinoma (ICD-O-3 8042/3). Tumour size on pathology: 50 mm. AJCC 6th edition staging: stage IIIB (best stage, from clinical TNM); clinical T4 N0 M0 (stage IIIB); pathologic TX. AJCC 7th edition staging: stage IIIA; clinical T4 N0 M0; pathologic TX NX MX. Summary stage: regional. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): extensive.

Follow-up
Last known free of lung cancer: day 24 (for ACRIN participants with lung cancer this field holds the diagnosis date).
